Somatic mutation profile of tumor specimen MP2PRT-PASNYX-TMP1-A (aliquot MP2PRT-PASNYX-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNYX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,303 days).
Specimen MP2PRT-PASNYX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c05f8b87-8711-4923-84e1-813535a8c8a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNYX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNYX-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2862c14-8678-4789-bb50-af91aec5f368

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, In Frame Del 2, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP1 | c.3742G>A p.E1248K (on ENST00000620786 / NM_001247997.1; = p.E1237K on NM_002956.2) | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs368279544; called by muse, mutect2
- EP300 | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV54338122; called by muse, mutect2
- INPP5B | c.1723G>A p.E575K (on ENST00000373023; = p.E495K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV100886521; called by muse, mutect2, varscan2
- LRRC7 | c.2858G>A p.R953H (on ENST00000651989 / NM_001370785.2; = p.R920H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs141932871; called by muse, mutect2
- OR56A1 | c.348C>G p.C116W | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs768332271; called by muse, mutect2
- PLPPR3 | c.1028_1030del p.K343del (on ENST00000520876 / NM_001270366.2; = p.K371del on NM_024888.2) | In Frame Del (DEL) | VAF 128/614 reads (21%) | catalogued as rs1236510407; called by pindel, varscan2
- PPARGC1B | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs752587311, COSV100495076, COSV58529171; called by muse, mutect2, varscan2
- ADGRF5 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC168 | c.8197C>G p.Q2733E | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- EPC1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- FLG2 | c.6063G>C p.R2021S | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIAA1109 | c.8447-1G>C p.X2816_splice | Splice Site (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- LTN1 | c.4641G>T p.Q1547H | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPARGC1A | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RBM26 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SETDB2 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SV2A | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 34/578 reads (6%) | called by muse, mutect2
- TLR8 | c.2524G>T p.V842F (on ENST00000218032 / NM_138636.5; = p.V860F on NM_016610.4) | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.721); called by muse, mutect2
- UQCC1 | c.888_890del p.D296del | In Frame Del (DEL) | VAF 50/294 reads (17%) | called by pindel, varscan2
- ARMCX5 | c.775C>T p.L259= | Silent (SNP) | VAF 40/602 reads (7%) | catalogued as rs752461022, COSV55767969; called by muse, mutect2
- EXOSC9 | c.480C>T p.F160= | Silent (SNP) | VAF 59/275 reads (21%) | called by muse, mutect2, varscan2
- LIMCH1 | c.693C>T p.S231= | Silent (SNP) | VAF 51/242 reads (21%) | catalogued as rs781005705; called by muse, mutect2, varscan2
- LONP1 | c.78C>A p.A26= | Silent (SNP) | VAF 72/711 reads (10%) | called by muse, mutect2
- OR11H12 | c.711G>C p.L237= | Silent (SNP) | VAF 28/784 reads (4%) | catalogued as COSV101612514; called by muse, mutect2
- PEX11G | c.480G>A p.A160= | Silent (SNP) | VAF 126/464 reads (27%) | catalogued as rs145919987; called by muse, mutect2, varscan2
- SYNM | c.378G>A p.A126= | Silent (SNP) | VAF 47/671 reads (7%) | catalogued as rs1450946584; called by muse, mutect2
- ZNF621 | c.408C>T p.F136= | Silent (SNP) | VAF 27/267 reads (10%) | called by muse, mutect2, varscan2
- CYP4F3 | c.199-1713C>T | Intron (SNP) | VAF 128/428 reads (30%) | catalogued as rs772217057, COSV55410641; called by muse, mutect2, varscan2
